Somatic mutation profile of tumor specimen BA3023D (aliquot aq-BA3023D) from BEATAML1.0 case 2149, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.6 years (10,066 days).
Specimen BA3023D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d059c35-d8b8-4228-9f48-ba9af2720116.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2204D (Solid Tissue Normal), aliquot aq-BA2204D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/997183bc-071e-4846-bfed-2d40de68f8b7

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Ins 4, Splice Region 1, Frame Shift Del 1, Intron 1, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- ASAP1 | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.321); catalogued as rs1275826175; called by muse, mutect2, varscan2
- BPIFC | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs376981555; called by muse, mutect2, varscan2
- DFFA | c.783+7G>A | Splice Region (SNP) | VAF 20/60 reads (33%) | catalogued as rs772455668; called by muse, varscan2
- ERBIN | c.2191C>G p.P731A | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs760006813; called by muse, mutect2, varscan2
- GOLGA6L10 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 72/542 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.316); catalogued as rs1220506694; called by muse, varscan2
- GOLGA8T | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 156/432 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1299151609; called by muse, mutect2, varscan2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2
- JAM2 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs200218663, COSV57256777; called by muse, mutect2, varscan2
- MMEL1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.215); catalogued as rs927596248; called by muse, varscan2
- NF1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as CM110507, CM1311446, COSV62212863; called by muse, mutect2, varscan2
- PTPN11 | c.853T>A p.F285I | Missense Mutation (SNP) | VAF 138/367 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM024733, CM086896, COSV61010689; called by muse, mutect2, varscan2
- SPTBN5 | c.8014G>A p.G2672R | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs756778746; called by muse, varscan2
- WT1 | c.1304-2A>G p.X435_splice | Splice Site (SNP) | VAF 108/253 reads (43%) | catalogued as COSV60078533; called by muse, mutect2, varscan2
- CPS1 | c.3940del p.S1314Pfs*5 | Frame Shift Del (DEL) | VAF 105/264 reads (40%) | called by mutect2, pindel*, varscan2
- CSDE1 | c.2209C>G p.R737G (on ENST00000358528 / NM_001007553.3; = p.R706G on NM_007158.6) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- CTNND2 | c.3146G>T p.R1049M | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DDX24 | c.1855G>T p.A619S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- DPP6 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUOX1 | c.2627_2628insTAGTT p.I877Sfs*6 | Frame Shift Ins (INS) | VAF 22/151 reads (15%) | called by mutect2, pindel
- GDF10 | c.633G>C p.K211N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, varscan2
- GOLGA6L10 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 46/515 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.158); called by muse, varscan2
- NF1 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFIC | c.1367dup p.A457Cfs*85 (on ENST00000443272 / NM_001245002.2; = p.A448Cfs*85 on NM_205843.3) | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, varscan2
- PCDH1 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- PRR7 | c.768C>G p.H256Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- RAD21 | c.1416dup p.P473Tfs*5 | Frame Shift Ins (INS) | VAF 26/81 reads (32%) | called by mutect2, pindel, varscan2
- TKTL2 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); called by muse, mutect2
- APBA2 | c.1101C>T p.I367= | Silent (SNP) | VAF 76/430 reads (18%) | catalogued as rs770286407; called by muse, mutect2, varscan2
- PPP1R9B | c.387G>T p.A129= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- RAX | c.900G>A p.P300= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- SLC6A18 | c.1734C>T p.P578= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs750730505, COSV99722209; called by muse, mutect2, varscan2
- VAMP2 | c.192C>T p.D64= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs750996677; called by muse, mutect2, varscan2
- VGF | c.258G>T p.L86= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CADM2 | c.62-75546G>A | Intron (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- PLIN1 | c.*655G>A | 3'UTR (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
